Somatic mutation profile of tumor specimen C3N-01383-03 (aliquot CPT0094230010_1) from CPTAC case C3N-01383, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 80.5 years (29,417 days).
Specimen C3N-01383-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 338c3639-6c1f-4258-bafd-34d3b228f1b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01383-31 (Blood Derived Normal), aliquot CPT0094270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c97e567c-9f5c-4f1b-99b1-10ad6293bee4

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Intron 4, Nonsense Mutation 4, 5'Flank 1, Splice Site 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 82/848 reads (10%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 56/620 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCB6 | c.2369A>G p.N790S | Missense Mutation (SNP) | VAF 45/648 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs199955293; called by muse, mutect2
- ADAMTS5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 54/826 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs752801493, COSV53183225; called by muse, mutect2
- BAHCC1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs549555237, COSV57023720; called by muse, mutect2, varscan2
- CCDC149 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200792138; called by muse, mutect2, varscan2
- CLASP2 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 55/714 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV56280376; called by muse, mutect2
- COL22A1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 64/593 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.545); catalogued as rs758355984; called by muse, mutect2, varscan2
- COL6A3 | c.9070G>A p.V3024I | Missense Mutation (SNP) | VAF 62/678 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs769756403, COSV55100929; called by muse, mutect2
- FAM47A | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 58/509 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.417); catalogued as COSV60497337; called by muse, mutect2, varscan2
- FNIP2 | c.2798A>T p.Q933L | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs1024480054; called by muse, mutect2
- IPO8 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 52/624 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs778254539, COSV56240309; called by muse, mutect2
- KRT1 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 40/660 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52866558; called by muse, mutect2
- MED12L | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1157763534, COSV56404780; called by muse, mutect2, varscan2
- MYPN | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 100/1000 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs763362861, COSV100590633; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEU4 | c.367C>T p.R123C (on ENST00000391969 / NM_001167602.3; = p.R135C on NM_080741.4) | Missense Mutation (SNP) | VAF 39/426 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs370244576; called by muse, mutect2
- OR14C36 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 56/560 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs145207343, COSV58602779; called by muse, mutect2
- OR5D14 | c.733T>A p.S245T | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565114056; called by muse, mutect2, varscan2
- PCED1A | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 66/793 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753469763; called by muse, mutect2
- RIMS2 | c.3548-1G>T p.X1183_splice | Splice Site (SNP) | VAF 38/237 reads (16%) | catalogued as COSV51672175, COSV99165552; called by muse, mutect2, varscan2
- SLC39A12 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs187451149; called by muse, mutect2, varscan2
- SLC40A1 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 33/478 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.284); catalogued as rs750595460; called by muse, mutect2
- SMAD4 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 59/442 reads (13%) | catalogued as COSV61691371; called by muse, mutect2, varscan2
- SPEG | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1559369507; called by muse, mutect2
- TMPRSS11B | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | catalogued as rs559293322; called by muse, mutect2, varscan2
- TNN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 43/610 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as COSV53421489; called by muse, mutect2
- TPR | c.637A>G p.R213G | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1174825005; called by muse, mutect2
- UNC79 | c.2317C>T p.R773C (on ENST00000393151 / NM_001346218.2; = p.R596C on NM_020818.5) | Missense Mutation (SNP) | VAF 68/821 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs781756182, COSV56376369; called by muse, mutect2
- ZNF331 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs752346719; called by muse, mutect2
- COPG2 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.049); called by muse, mutect2
- COX6C | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FMN2 | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- GCLC | c.578G>A p.R193K (on ENST00000643939; = p.R191K on NM_001498.4) | Missense Mutation (SNP) | VAF 62/692 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.051); called by muse, mutect2
- HAUS8 | c.1052A>G p.D351G | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNB1 | c.211T>G p.F71V | Missense Mutation (SNP) | VAF 37/425 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.148); called by muse, mutect2
- KANSL1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 40/450 reads (9%) | called by muse, mutect2
- KRT80 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MCM8 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC2 | c.2528C>T p.T843I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- MYT1L | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 46/633 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TIPIN | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP23 | c.2433C>T p.G811= | Silent (SNP) | VAF 43/534 reads (8%) | catalogued as rs1199537892; called by muse, mutect2
- BNC1 | c.2904G>A p.S968= | Silent (SNP) | VAF 55/479 reads (11%) | catalogued as rs1021377126, COSV61757413; called by muse, mutect2, varscan2
- CTNNA2 | c.2001C>T p.S667= | Silent (SNP) | VAF 24/298 reads (8%) | catalogued as rs368214934; called by muse, mutect2
- DCAF4L2 | c.636C>T p.N212= | Silent (SNP) | VAF 122/731 reads (17%) | catalogued as rs866117569; called by muse, mutect2, varscan2
- ERCC8 | c.129C>T p.G43= | Silent (SNP) | VAF 29/377 reads (8%) | catalogued as rs145518936; called by muse, mutect2
- FLG2 | c.93T>C p.G31= | Silent (SNP) | VAF 34/417 reads (8%) | called by muse, mutect2
- HMCN1 | c.4317T>A p.T1439= | Silent (SNP) | VAF 44/494 reads (9%) | called by muse, mutect2
- NRDE2 | c.906C>T p.S302= | Silent (SNP) | VAF 46/429 reads (11%) | catalogued as rs375950270; called by muse, mutect2, varscan2
- RYR1 | c.12654C>T p.F4218= | Silent (SNP) | VAF 57/736 reads (8%) | catalogued as rs1294294978, COSV62094637; called by muse, mutect2
- SCEL | c.498G>A p.P166= | Silent (SNP) | VAF 41/354 reads (12%) | catalogued as rs528874271; called by muse, mutect2, varscan2
- SLC29A2 | c.577C>T p.L193= | Silent (SNP) | VAF 76/788 reads (10%) | called by muse, mutect2
- SLCO5A1 | c.2190C>T p.N730= | Silent (SNP) | VAF 58/772 reads (8%) | catalogued as COSV52668177; called by muse, mutect2
- SUMF2 | c.462C>T p.G154= (on ENST00000652303; = p.G135= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- VWA5B1 | c.2652C>T p.S884= | Silent (SNP) | VAF 58/642 reads (9%) | catalogued as rs766432055; called by muse, mutect2
- AL645933.1 | chr6:31463961 C>G | 5'Flank (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- CA13 | c.37+522T>A | Intron (SNP) | VAF 44/476 reads (9%) | called by muse, mutect2
- IL1RAP | c.538-4962A>T | Intron (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- LYRM4 | c.208-3806G>A | Intron (SNP) | VAF 26/205 reads (13%) | catalogued as rs1316186537; called by muse, mutect2, varscan2
- MIRLET7A3 | n.59A>G | RNA (SNP) | VAF 26/333 reads (8%) | catalogued as rs970921980; called by muse, mutect2
- TFAP2C | c.-4C>T | 5'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs1423247789, COSV52373804; called by muse, varscan2
- TFR2 | c.614+18C>T | Intron (SNP) | VAF 35/344 reads (10%) | catalogued as rs1398792897; called by muse, mutect2, varscan2
